Somatic mutation profile of tumor specimen TARGET-10-PASZJW-03A (aliquot TARGET-10-PASZJW-03A-01D) from TARGET case TARGET-10-PASZJW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.0 years (10,946 days).
Specimen TARGET-10-PASZJW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78f5ebb4-6b9f-4b82-8aca-eed81c6e9115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASZJW-10A (Blood Derived Normal), aliquot TARGET-10-PASZJW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38d7c5fa-9c75-4f9e-bdad-7bf18e5296ac

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 3, RNA 2, 5'Flank 1, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL14A1 | c.4266C>A p.C1422* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52861046; called by muse, mutect2, varscan2
- EPHA10 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60404551; called by muse, mutect2, varscan2
- GALP | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs541821181, COSV62000611; called by muse, mutect2, varscan2
- GAPDHS | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs202022657, COSV55880431; called by muse, mutect2, varscan2
- NANOS2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58025183, COSV58025531; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- OR51D1 | c.653C>A p.S218* | Nonsense Mutation (SNP) | VAF 42/93 reads (45%) | catalogued as COSV62914440; called by muse, mutect2, varscan2
- PGR | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV104374546, COSV54799524; called by muse, mutect2, varscan2
- PIK3C2B | c.2594G>A p.W865* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV65812978; called by muse, mutect2, varscan2
- RTL1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs745760683, COSV66017178; called by muse, mutect2, varscan2
- SESN2 | c.901+1G>T p.X301_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV53428379; called by muse, mutect2
- TECPR1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457116947, COSV65784318; called by muse, mutect2, varscan2
- ATP12A | c.2592C>A p.L864= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- CUX2 | c.1185G>A p.L395= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs1471046304; called by muse, mutect2, varscan2
- FUOM | c.144C>A p.I48= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- PRAG1 | c.3324G>A p.A1108= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV58157172; called by muse, mutect2, varscan2
- SH3TC2 | c.2403C>T p.C801= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs763234510; called by muse, mutect2, varscan2
- UGT2B7 | c.168G>A p.L56= | Silent (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- C9orf62 | n.618G>T | RNA (SNP) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- CCL23 | c.*76dup | 3'UTR (INS) | VAF 24/48 reads (50%) | called by mutect2, varscan2
- GVINP1 | n.2927G>A | RNA (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- RNU1-6P | chr1:16536045 C>T | 5'Flank (SNP) | VAF 28/224 reads (13%) | catalogued as rs528474120; called by muse, mutect2, varscan2
